Somatic mutation profile of tumor specimen ALCH-AE4W-TTP1-A (aliquot ALCH-AE4W-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE4W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,433 days).
Specimen ALCH-AE4W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 589f7c66-898b-4184-a62a-47527f46a00b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE4W-NB1-A (Blood Derived Normal), aliquot ALCH-AE4W-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fc971e5-0166-4c18-9a37-fa759d0bce8d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGCR6L | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- HDGFL1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.044); called by muse, mutect2
- SPATA12 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 13/455 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.713); called by muse, mutect2
